Somatic mutation profile of tumor specimen MP2PRT-PARSGC-TBP1-A (aliquot MP2PRT-PARSGC-TBP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PARSGC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,133 days).
Specimen MP2PRT-PARSGC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2970beaf-f9e8-4744-9546-837016e55b33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARSGC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARSGC-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/933ee8bd-67f0-4384-a9a5-fbd9ee09cdad

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 1, Intron 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 275/275 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 154/330 reads (47%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ARFGEF3 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 133/420 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758792709; called by muse, mutect2, varscan2
- EVX2 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 186/379 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV57962625; called by muse, mutect2, varscan2
- FBLN7 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 311/579 reads (54%) | catalogued as rs369753216, COSV55617048; called by muse, mutect2, varscan2
- GNAI3 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 156/320 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1206316589; called by muse, mutect2, varscan2
- OSBPL5 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 235/508 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs866421233; called by muse, mutect2, varscan2
- SLK | c.3370C>T p.H1124Y | Missense Mutation (SNP) | VAF 153/299 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV59825205; called by muse, mutect2, varscan2
- UGT1A10 | c.807G>C p.M269I | Missense Mutation (SNP) | VAF 210/423 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV60838931; called by muse, mutect2, varscan2
- ZNRF4 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 239/541 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs762078994; called by muse, mutect2, varscan2
- OTOF | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 271/583 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- SKI | c.149A>C p.E50A | Missense Mutation (SNP) | VAF 311/611 reads (51%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TBC1D9B | c.2727C>T p.S909= | Splice Region (SNP) | VAF 147/299 reads (49%) | called by muse, mutect2, varscan2
- EPHB2 | c.1143C>T p.Y381= | Silent (SNP) | VAF 233/498 reads (47%) | catalogued as rs375578940; called by muse, mutect2, varscan2
- GRID2 | c.2140C>A p.R714= | Silent (SNP) | VAF 28/500 reads (6%) | catalogued as COSV56265407; called by muse, mutect2
- IRX2 | c.318G>T p.A106= | Silent (SNP) | VAF 148/286 reads (52%) | called by muse, varscan2
- SPATA31E1 | c.1569C>G p.T523= | Silent (SNP) | VAF 229/549 reads (42%) | catalogued as COSV100349712; called by muse, mutect2, varscan2
- SPEF2 | c.1686A>T p.G562= | Silent (SNP) | VAF 145/295 reads (49%) | called by muse, mutect2, varscan2
- RASSF1 | c.369+665C>G | Intron (SNP) | VAF 239/506 reads (47%) | catalogued as COSV51601528; called by muse, mutect2, varscan2
